Somatic mutation profile of tumor specimen ALCH-B0CL-TTP1-A (aliquot ALCH-B0CL-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0CL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.7 years (21,439 days).
Specimen ALCH-B0CL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45157460-6d3b-44cf-9c48-640cf48cc55d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0CL-NB1-A (Blood Derived Normal), aliquot ALCH-B0CL-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bddd027e-e263-44b7-ad69-328c3ac61e64

The open-access MAF lists 25 somatic variants for this specimen: 13 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 9, Intron 1, 3'UTR 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 85/619 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- COL4A4 | c.2675C>A p.P892H | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs774847155, COSV61631048; called by muse, mutect2, varscan2
- GOLT1A | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149764346; called by muse, mutect2
- PCDH9 | c.2374A>G p.M792V | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.179); catalogued as rs555154692; called by muse, mutect2, varscan2
- PDZD7 | c.2198C>T p.T733I | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1029073752; called by muse, mutect2, varscan2
- RPL35 | c.40A>G p.K14E | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs750326021; called by muse, mutect2, varscan2
- ZC3H7B | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.406); catalogued as COSV60965074; called by muse, mutect2, varscan2
- FAM177B | c.72G>C p.R24S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, varscan2
- KMT2B | c.3499G>A p.G1167S | Missense Mutation (SNP) | VAF 19/438 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- MUC1 | c.3323T>C p.V1108A (on ENST00000611571 / NM_001371720.1; = p.V119A on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 136/333 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHF3 | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM10 | c.1107_1109dup p.L370dup | In Frame Ins (INS) | VAF 51/223 reads (23%) | called by mutect2, pindel, varscan2
- ZC3H12B | c.2040G>A p.M680I | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); called by mutect2, varscan2
- AVIL | c.2286A>C p.A762= | Silent (SNP) | VAF 11/153 reads (7%) | called by muse, mutect2
- CFH | c.543C>T p.G181= | Silent (SNP) | VAF 24/298 reads (8%) | called by muse, mutect2
- CHST3 | c.603C>T p.Y201= | Silent (SNP) | VAF 41/393 reads (10%) | catalogued as rs121908619, CM082558; called by muse, mutect2, varscan2
- HSPG2 | c.8004C>A p.G2668= | Silent (SNP) | VAF 26/421 reads (6%) | catalogued as COSV65975646; called by muse, mutect2
- IGHM | c.1140C>T p.S380= | Silent (SNP) | VAF 26/294 reads (9%) | catalogued as rs782220166; called by muse, mutect2
- KMT2E | c.5179T>C p.L1727= | Silent (SNP) | VAF 12/234 reads (5%) | called by muse, mutect2
- PTPRN2 | c.2973G>A p.T991= | Silent (SNP) | VAF 18/236 reads (8%) | catalogued as rs200754252; called by muse, mutect2
- SLC13A4 | c.1485C>T p.S495= | Silent (SNP) | VAF 20/162 reads (12%) | called by muse, mutect2, varscan2
- ZNF429 | c.1101G>A p.K367= | Silent (SNP) | VAF 5/84 reads (6%) | catalogued as rs1244528297, COSV61915124; called by muse, mutect2
- MMAB | c.*1307G>A | 3'UTR (SNP) | VAF 10/139 reads (7%) | called by muse, mutect2
- SCML2P1 | n.1046C>T | RNA (SNP) | VAF 18/206 reads (9%) | catalogued as rs146243044; called by muse, mutect2
- TNNT3 | c.116-18C>T | Intron (SNP) | VAF 43/446 reads (10%) | catalogued as rs1428177094; called by muse, mutect2, varscan2
